Surgical pathology report (de-identified scan), TCGA case TCGA-L5-A4OG, project TCGA-ESCA (Esophageal Carcinoma), tissue source site University of Michigan, specimen TCGA-L5-A4OG-01A (Primary Tumor).

[page 1 of 2]
PREVIOUS DIAGNOSIS INQUIRY

PAGE #: 1
SEX: F

PROCEDURE: SPS

Source of Specimen: Esophagus. Incidentally discovered distal esophageal adenocarcinoma which may well be arising in Barrett's mucosa. Operative Procedure: Transhiatal esophagectomy. Specimen submitted: Distal esophagus and proximal stomach.

ICD-0-3
adenocarcinoma, NOS 8140/3
Site: distal third, esophagus

C45.5
10/9/12

PROCEDURE: SPGD

1. "Distal esophagus, proximal stomach." Received in formalin in a medium container is a previously opened resection specimen containing a 9.2 cm long esophagus and 3.0 cm long segment of proximal stomach. The proximal stomach is remarkable for a 1.5 x 3.9 (near circumferential) cm light brown, granular scar, with the proximal aspect abutting the GE junction, and the distal aspect 1.9 cm from the closest gastric margin.

NOTE: A portion of the mucosa does not have underlying submucosa and muscularis. Up to five possible lymph nodes are identified in the perigastric adipose. The gastric margin is inked green and the surrounding fat inked black. The ulcer is serially sectioned to reveal involvement restricted to the mucosa, with possible cystic change in the deeper areas of the mucosa.

1A. Closest gastric margin (without ulcer).

1B. Five possible perigastric lymph nodes.

1C-J. Ulcer including esophageal and gastric mucosa.

2. "Cervical esophageal margin." Received in formalin in a small container is a 2.0 x 0.5 x 0.3 cm esophageal donut with unremarkable mucosa.

PROCEDURE: SPMI

ESOPHAGUS, GASTROESOPHAGEAL JUNCTION, INCLUDING CARDIA,
CARCINOMA (RESECTION SPECIMENS):

=====

LOCATION: Lower esophagus

SIZE: Microscopic foci arising in extensive high grade dysplasia.

TYPE OF CARCINOMA: Adenocarcinoma not arising in barrett's mucosa

GRADE: Well differentiated

DEPTH OF INVASION: Lamina propria and muscularis mucosa

HAS IT BEEN TREATED PREOPERATIVELY WITH CHEMO/RADIATION THERAPY? No

[page 2 of 2]
PREVIOUS DIAGNOSIS INQUIRY

REPORT DATE: [REDACTED]

PAGE #: 2

SEX: F

NUMBER OF POSITIVE LYMPH NODES / TOTAL NUMBER OF NODES EXAMINED: 0/5

DISTANT METASTASIS: Unknown

RESECTION MARGIN INVOLVED: No

pT1a N0

PROCEDURE: SPDX [REDACTED]

1&2. Distal esophagus and proximal stomach, resection: Well-differentiated adenocarcinoma, invading into the muscularis mucosae and arising in extensive high grade dysplasia. Five lymph nodes negative for carcinoma. Margins free. Please see TEMPLATE for details.

I, [REDACTED], the signing staff pathologist, have personally examined and interpreted the slides from this case.

Histology Discrepancy		
Previous Pathology History		
Diagnosis Discrepancy Noted		
Reviewed Initials	Date Reviewed: 10/19/12	

Source: NCI Genomic Data Commons file 92b7a234-23f7-4fb2-ba0a-8d883b5628d8 (TCGA-L5-A4OG.2EEC7CE1-9800-4DBC-838B-D526D89382F4.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).